Somatic mutation profile of tumor specimen TCGA-EE-A29Q-06A (aliquot TCGA-EE-A29Q-06A-11D-A197-08) from TCGA case TCGA-EE-A29Q, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.2 years (26,737 days).
Specimen TCGA-EE-A29Q-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee8bf404-4c02-4543-ade2-acf238ed3a79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29Q-10A (Blood Derived Normal), aliquot TCGA-EE-A29Q-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5acc676-57af-4cd0-b921-6dae0be54b85

The open-access MAF lists 354 somatic variants for this specimen: 228 protein-altering or splice-affecting, 119 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 119, Nonsense Mutation 14, Splice Region 5, Intron 3, 3'Flank 2, RNA 2, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.7540G>A p.G2514R | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs363811, CM025900, CM077253, COSV57326105; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 75/158 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3880C>T p.R1294C | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); catalogued as rs139771120; called by muse, mutect2, varscan2
- ACBD4 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV58852999; called by muse, varscan2
- ADAM11 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs200895725, COSV52348661; called by muse, mutect2, varscan2
- ADAMTS12 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435327641, COSV61273094; called by muse, mutect2, varscan2
- ADCK5 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58234981; called by muse, mutect2, varscan2
- AIPL1 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51508264; called by muse, mutect2, varscan2
- AKR7A3 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as rs1244729324, COSV64389534; called by muse, mutect2, varscan2
- ANO4 | c.2492G>A p.R831Q (on ENST00000392977 / NM_001286615.2; = p.R796Q on NM_178826.4) | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as rs868314489, COSV54590940; called by muse, mutect2, varscan2
- ANXA10 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as rs1384088237, COSV63739855; called by muse, mutect2, varscan2
- AP1B1 | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as COSV58021663; called by muse, mutect2, varscan2
- APBB1IP | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV63076594; called by muse, mutect2, varscan2
- APOB | c.7828G>A p.A2610T | Missense Mutation (SNP) | VAF 278/577 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV51946515; called by muse, mutect2, varscan2
- ARFGAP1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV62263727; called by muse, mutect2, varscan2
- ARHGAP22 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs867270392, COSV50965914; called by muse, mutect2, varscan2
- ART5 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs767744521, COSV63364176; called by muse, mutect2, varscan2
- AS3MT | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs755170490, COSV54918329; called by muse, mutect2, varscan2
- ASAP3 | c.2544C>T p.F848= | Splice Region (SNP) | VAF 48/104 reads (46%) | catalogued as COSV60877053; called by muse, varscan2
- ASTN1 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758252814, COSV62502496; called by muse, mutect2, varscan2
- ASXL3 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs769342199, COSV52468216; called by muse, mutect2, varscan2
- ATP10A | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.18); catalogued as COSV63521356; called by muse, varscan2
- BIN2 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | catalogued as rs763415924, COSV57203665; called by muse, mutect2, varscan2
- BIRC3 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 70/114 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV54818913; called by muse, varscan2
- BMPER | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs757194668, COSV51827473; called by muse, mutect2, varscan2
- BPIFB2 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV50068787; called by muse, mutect2, varscan2
- C17orf75 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV56753783; called by muse, mutect2, varscan2
- C4orf45 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.244); catalogued as rs1469815248, COSV71701274; called by muse, mutect2, varscan2
- C9orf24 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52625175; called by muse, mutect2, varscan2
- CARM1 | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV59002403; called by muse, mutect2, varscan2
- CASS4 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs747288992, COSV64386490, COSV64387137; called by muse, mutect2, varscan2
- CCDC173 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0.09); catalogued as COSV69572467, COSV69572787; called by muse, mutect2, varscan2
- CCDC60 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59548198; called by muse, mutect2
- CCT8L2 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.16); catalogued as rs771781798, COSV63463384; called by muse, mutect2, varscan2
- CD200 | c.862C>T p.R288W (on ENST00000473539 / NM_001004196.3; = p.R263W on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs929133602, COSV59864169; called by muse, mutect2, varscan2
- CDH23 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1435371810, COSV99822881; called by muse, mutect2, varscan2
- CEACAM20 | c.1264C>T p.L422F | Missense Mutation (SNP) | VAF 165/380 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1191551402, COSV57602699; called by muse, mutect2, varscan2
- CLCN6 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 116/256 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56742244; called by muse, mutect2, varscan2
- CLDN25 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV101493612; called by muse, mutect2, varscan2
- CMKLR1 | c.1112G>A p.G371D (on ENST00000312143 / NM_001142344.2; = p.G369D on NM_004072.3) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as rs756181043, COSV100379551; called by muse, mutect2, varscan2
- CNOT6 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV56159300, COSV56163363; called by muse, mutect2, varscan2
- CNTN4 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as rs1258498683, COSV100639525; called by muse, mutect2, varscan2
- CNTN4 | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1476197735, COSV100639526, COSV61880065; called by muse, mutect2, varscan2
- CNTN5 | c.2166C>T p.V722= | Splice Region (SNP) | VAF 16/33 reads (48%) | catalogued as COSV54341340; called by muse, mutect2, varscan2
- COL4A4 | c.4335G>A p.G1445= | Splice Region (SNP) | VAF 10/13 reads (77%) | catalogued as rs762830099, COSV61634869; called by muse, mutect2, varscan2
- CPA1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782561684, CM139187, COSV50568458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE5 | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55198754; called by muse, mutect2, varscan2
- CRB1 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs563857130, COSV66328727, COSV66328731; called by muse, mutect2, varscan2
- CSNK1A1 | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55798983; called by muse, mutect2, varscan2
- CSNK1A1 | c.286A>T p.S96C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99939660; called by muse, mutect2, varscan2
- CWH43 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56941955; called by muse, varscan2
- CWH43 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV56936109, COSV56942244; called by muse, varscan2
- DAAM2 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51383128; called by muse, mutect2, varscan2
- DCAF8 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV58785361; called by muse, mutect2, varscan2
- DECR2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54795768; called by muse, mutect2, varscan2
- DICER1 | c.3187T>G p.C1063G | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.869); catalogued as COSV58625413; called by muse, mutect2, varscan2
- DMBT1 | c.3511G>A p.A1171T (on ENST00000338354 / NM_001377530.1; = p.A672T on NM_004406.3) | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV57554097; called by muse, mutect2, varscan2
- DNAH10 | c.268C>G p.Q90E (on ENST00000409039; = p.Q29E on NM_207437.3) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101291877, COSV68998753; called by muse, mutect2, varscan2
- DNAH17 | c.5770C>T p.R1924W | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768967388, COSV67752677; called by muse, mutect2, varscan2
- DNAH5 | c.5993G>A p.G1998E | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54243321; called by muse, mutect2, varscan2
- DNAH9 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52364140; called by muse, mutect2, varscan2
- DNAJC11 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV50011449; called by muse, mutect2, varscan2
- DNMBP | c.3854C>T p.P1285L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60630529; called by muse, varscan2
- DNMT3B | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV52415535; called by muse, mutect2, varscan2
- DPF2 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52890796; called by muse, mutect2, varscan2
- DSC1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as COSV57149509; called by muse, mutect2, varscan2
- DSC2 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51867691; called by muse, mutect2, varscan2
- DSG4 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV57388796, COSV57395325; called by muse, mutect2, varscan2
- DTL | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV65342955; called by muse, mutect2, varscan2
- DUOX2 | c.3361G>A p.D1121N | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV66533545; called by muse, mutect2, varscan2
- EIF1AX | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 75/103 reads (73%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as COSV63309435; called by muse, mutect2, varscan2
- EIF4G3 | c.2113C>T p.Q705* | Nonsense Mutation (SNP) | VAF 98/215 reads (46%) | catalogued as COSV51689965; called by muse, mutect2, varscan2
- ELOA | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV69310951; called by muse, mutect2, varscan2
- EPHB6 | c.2443C>T p.L815F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV63892650; called by muse, mutect2, varscan2
- FAM155A | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs921482748, COSV65578670; called by muse, mutect2, varscan2
- FARP1 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 71/106 reads (67%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.993); catalogued as COSV60344194; called by muse, mutect2, varscan2
- FAT4 | c.12983G>A p.R4328K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV58701132; called by muse, mutect2, varscan2
- FBXO11 | c.1745C>T p.P582L (on ENST00000403359 / NM_001190274.2; = p.P498L on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs267599394, COSV57024219; called by muse, mutect2, varscan2
- FLG | c.11711C>T p.S3904F | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV64245889; called by muse, mutect2, varscan2
- FMN2 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.326); catalogued as rs752547483, COSV60425632; called by muse, mutect2, varscan2
- FREM2 | c.4282G>A p.G1428R | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV54841064, COSV54846812; called by muse, mutect2, varscan2
- GALNT9 | c.1568C>T p.S523F (on ENST00000328957 / NM_001122636.2; = p.S157F on NM_021808.3) | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV61101907; called by muse, mutect2, varscan2
- GCOM1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.212); catalogued as rs866578359, COSV51094729; called by muse, mutect2, varscan2
- GCSAML | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1427262828, COSV63577953, COSV63579783; called by muse, mutect2, varscan2
- GFPT2 | c.1508G>A p.R503K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs770743216, COSV53811143; called by muse, mutect2
- GFRAL | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 85/118 reads (72%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs368896330, COSV61230253; called by muse, mutect2, varscan2
- GPR148 | c.833T>A p.V278E | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1036030577, COSV59309061; called by muse, mutect2, varscan2
- GTF2A1 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV53338175; called by muse, mutect2, varscan2
- GUCY1A1 | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.99); PolyPhen benign (0.16); catalogued as rs761897078, COSV56649671, COSV56650951; called by muse, mutect2, varscan2
- GUCY2C | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53793930; called by muse, mutect2, varscan2
- HACE1 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV53505790; called by muse, mutect2, varscan2
- HECW1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as rs866226633, COSV67832285, COSV67832713; called by mutect2, varscan2
- HEXA | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV51507965; called by muse, mutect2, varscan2
- HS3ST4 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV58817016, COSV58824926; called by muse, mutect2, varscan2
- HTR7 | c.662G>A p.W221* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | catalogued as COSV53291111; called by muse, mutect2, varscan2
- HYDIN | c.10280C>T p.S3427F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66859649; called by muse, mutect2
- ICE1 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV56829697; called by muse, mutect2, varscan2
- IGHG3 | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 150/375 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as rs766198118; called by muse, mutect2, varscan2
- IRAK1BP1 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.45); PolyPhen benign (0.125); catalogued as COSV64048694; called by muse, mutect2, varscan2
- ITGAV | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99655435; called by muse, mutect2, varscan2
- KBTBD2 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); catalogued as rs1156335701, COSV58364059; called by muse, mutect2, varscan2
- KIAA1109 | c.494A>G p.D165G | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1220237323, COSV52686453; called by muse, mutect2, varscan2
- KIRREL1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63285100, COSV63290126; called by muse, mutect2, varscan2
- KRT37 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 78/166 reads (47%) | catalogued as COSV56659335; called by muse, mutect2, varscan2
- LMTK2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52001344; called by muse, mutect2, varscan2
- LRP5 | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV99592454; called by mutect2, varscan2
- LTBP2 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56211844; called by muse, mutect2, varscan2
- LY6D | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as COSV56661583; called by muse, mutect2, varscan2
- M1AP | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99304375; called by muse, mutect2, varscan2
- MAGEB6B | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs1258290921; called by muse, mutect2, varscan2
- MAP3K21 | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.055); catalogued as COSV64042316; called by muse, mutect2, varscan2
- MAP3K9 | c.2534C>T p.S845F (on ENST00000554752 / NM_001284230.1; = p.S859F on NM_033141.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV67122459; called by muse, mutect2, varscan2
- MARCHF1 | c.242G>A p.R81K (on ENST00000274056; = p.R64K on NM_017923.4) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV56826525; called by muse, mutect2, varscan2
- MCM3 | c.1534C>T p.L512F (on ENST00000229854 / NM_001366374.2; = p.L502F on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV57718851; called by muse, mutect2, varscan2
- MCRS1 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1412755169, COSV59460925; called by mutect2, varscan2
- ME1 | c.1271C>T p.T424I | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780950476, COSV63841611, COSV63843281; called by muse, mutect2, varscan2
- MEGF6 | c.1186G>C p.G396R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.62); catalogued as COSV53893791; called by muse, mutect2, varscan2
- MEI1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV55905859; called by muse, mutect2, varscan2
- METTL21A | c.329T>C p.L110S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV55881890; called by muse, mutect2, varscan2
- MGAM | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs775838690, COSV72075123; called by mutect2, varscan2
- MGAM | c.4550G>A p.G1517D | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075291; called by muse, mutect2
- MKX | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV101008849; called by muse, mutect2, varscan2
- MROH2B | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV68187690; called by muse, mutect2, varscan2
- MROH5 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as rs780202794, COSV71302417; called by muse, mutect2, varscan2
- MRPL42 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs763030799, COSV62356912; called by muse, mutect2, varscan2
- MSR1 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50523234; called by muse, mutect2, varscan2
- MUC16 | c.36829C>T p.P12277S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.222); catalogued as COSV67482477; called by muse, mutect2, varscan2
- MYO18B | c.6625G>A p.E2209K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs545281386, COSV59127218; called by muse, varscan2
- MYO3A | c.4568G>A p.R1523Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs777250600, COSV56318222; called by muse, mutect2, varscan2
- NCKAP1L | c.1348G>T p.V450L | Missense Mutation (SNP) | VAF 66/104 reads (63%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV53210558; called by muse, mutect2, varscan2
- NEK1 | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1454883910, COSV71456856; called by mutect2, varscan2
- NEK5 | c.1970G>A p.W657* | Nonsense Mutation (SNP) | VAF 41/52 reads (79%) | catalogued as rs754223539, COSV62881297; called by muse, mutect2, varscan2
- NIPBL | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as CM148597, COSV56961072; called by muse, mutect2, varscan2
- NLRP4 | c.1739T>A p.I580N | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV56720045; called by muse, mutect2, varscan2
- NPAS4 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1477558323, COSV60651946; called by muse, mutect2, varscan2
- NPNT | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as rs770084338, COSV59752271; called by muse, varscan2
- NRK | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV54599821; called by muse, mutect2, varscan2
- NXPE3 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV56291524; called by muse, mutect2, varscan2
- OR10A3 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV62459981; called by muse, mutect2, varscan2
- OR2AK2 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.463); catalogued as rs764756091, COSV63550094, COSV63550148; called by muse, mutect2, varscan2
- OR2G6 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58573668; called by muse, mutect2, varscan2
- OR4C16 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 98/158 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs267602970, COSV58941019; called by muse, varscan2
- OR52R1 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs866937276, COSV61887873; called by muse, mutect2, varscan2
- ORAI2 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs765364777, COSV62690205; called by muse, varscan2
- OTOP3 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60914398; called by muse, mutect2, varscan2
- OTULINL | c.258G>A p.R86= | Splice Region (SNP) | VAF 28/74 reads (38%) | catalogued as COSV57034573; called by muse, mutect2, varscan2
- P3H2 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs753266253, COSV60025913; called by muse, mutect2
- PADI3 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV64934134; called by muse, mutect2, varscan2
- PADI3 | c.411G>A p.R137= | Splice Region (SNP) | VAF 41/90 reads (46%) | catalogued as COSV64933863, COSV64935104; called by muse, mutect2, varscan2
- PAMR1 | c.677T>C p.F226S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53515259; called by muse, mutect2, varscan2
- PCDH7 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62341961; called by muse, mutect2, varscan2
- PCDHB10 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99504783; called by muse, mutect2, varscan2
- PCNX2 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV50848177; called by muse, mutect2, varscan2
- PDGFRA | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.095); catalogued as COSV57264594, COSV57271693; called by muse, mutect2, varscan2
- PFAS | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as COSV58982312; called by muse, varscan2
- PFAS | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs555268035, COSV58982324; called by muse, mutect2, varscan2
- PGAM4 | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 53/87 reads (61%) | catalogued as COSV100431401; called by muse, mutect2, varscan2
- PHF20 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV59187679, COSV59187965; called by muse, mutect2, varscan2
- PI4KA | c.5711C>T p.S1904F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55418913; called by muse, mutect2, varscan2
- PIK3C2A | c.1708C>T p.Q570* | Nonsense Mutation (SNP) | VAF 38/53 reads (72%) | catalogued as COSV56405585; called by muse, mutect2, varscan2
- PKHD1 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61873886; called by muse, mutect2, varscan2
- PLB1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as COSV59825777; called by muse, mutect2, varscan2
- PLD1 | c.3094C>T p.R1032* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as rs746291174, COSV60572332; called by muse, mutect2, varscan2
- PPIAL4G | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.445); catalogued as rs1304328347, COSV70086836; called by muse, mutect2, varscan2
- PPP6R3 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV55733128; called by muse, mutect2, varscan2
- PRF1 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV64615620; called by muse, mutect2, varscan2
- RACK1 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV65175057; called by muse, varscan2
- RASAL2 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62719618; called by muse, mutect2, varscan2
- RASAL2 | c.2288G>A p.R763K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.777); catalogued as COSV62719634; called by muse, mutect2, varscan2
- RGS7 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV58533519, COSV58548943; called by muse, mutect2, varscan2
- RIMBP2 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs774346465, COSV55480309; called by muse, varscan2
- RIMBP2 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1297113279, COSV55477408, COSV55480323; called by muse, mutect2, varscan2
- RIMS2 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV68492134; called by muse, mutect2, varscan2
- RP1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV55111994, COSV55119400; called by muse, mutect2, varscan2
- RUNDC3A | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56588653; called by muse, mutect2, varscan2
- RUNX1T1 | c.1175G>A p.W392* (on ENST00000265814 / NM_001198628.1; = p.W365* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 69/138 reads (50%) | catalogued as COSV56158041; called by muse, mutect2, varscan2
- SCAF8 | c.2663C>T p.P888L | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV65793207; called by muse, mutect2, varscan2
- SCN3A | c.5422A>T p.I1808L | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV51819263; called by muse, mutect2, varscan2
- SEMA3F | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); catalogued as rs774926819, COSV50033481; called by muse, mutect2, varscan2
- SEZ6L2 | c.1243C>A p.P415T (on ENST00000308713 / NM_001114099.3; = p.P345T on NM_012410.4) | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV58101984; called by muse, mutect2, varscan2
- SH2D7 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.129); catalogued as COSV60927453; called by muse, mutect2, varscan2
- SH3RF2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs140312306; called by muse, mutect2, varscan2
- SIRPB1 | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 45/103 reads (44%) | catalogued as COSV53540162; called by muse, mutect2, varscan2
- SLAMF9 | c.425T>A p.F142Y | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV63637106; called by mutect2, varscan2
- SLC14A2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54912966; called by muse, mutect2, varscan2
- SLC27A6 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52486047; called by muse, mutect2, varscan2
- SLIT1 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV56595680, COSV56595899; called by muse, mutect2, varscan2
- SLIT2 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV56565528, COSV56587278; called by muse, mutect2, varscan2
- SNAPC1 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1000832247, COSV53520151, COSV53520712; called by muse, mutect2, varscan2
- SNRPA1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV54258241; called by muse, mutect2, varscan2
- SOX6 | c.2090C>T p.T697I (on ENST00000528429 / NM_001145819.2; = p.T670I on NM_017508.3) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57053835; called by muse, mutect2, varscan2
- SP140 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1326608474, COSV59453400; called by muse, mutect2, varscan2
- SPAG17 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs982562781, COSV60459312; called by muse, mutect2, varscan2
- SPANXN5 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs1433237138, COSV64968830; called by muse, mutect2, varscan2
- SPPL2B | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs759998971, COSV101194631, COSV66317261; called by muse, varscan2
- SRRM2 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as rs757271905, COSV57078653; called by muse, mutect2, varscan2
- SRSF6 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs749119116, COSV54828575; called by mutect2, varscan2
- SSTR1 | c.388T>G p.C130G | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57457149; called by muse, mutect2, varscan2
- ST6GAL2 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | PolyPhen benign (0.071); catalogued as rs1424535500, COSV64530626; called by muse, mutect2, varscan2
- STAB2 | c.7594G>A p.D2532N | Missense Mutation (SNP) | VAF 88/149 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs750917891, COSV66335037; called by muse, varscan2
- STN1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as rs760964853, COSV56545462, COSV56545576; called by muse, mutect2, varscan2
- THEMIS | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV64069310; called by muse, mutect2, varscan2
- TMEM132B | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 67/103 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs760140118, COSV54750120; called by muse, mutect2, varscan2
- TMEM63C | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100029627; called by muse, mutect2, varscan2
- TNRC6B | c.3703C>T p.P1235S (on ENST00000454349 / NM_001162501.2; = p.P1125S on NM_015088.3) | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57304188; called by muse, mutect2, varscan2
- TOX | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63843065; called by muse, mutect2, varscan2
- TRANK1 | c.6764C>T p.S2255F | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV57159818; called by muse, mutect2, varscan2
- TRANK1 | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 95/217 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57153036; called by muse, mutect2, varscan2
- TTN | c.82204G>A p.E27402K (on ENST00000591111; = p.E19978K on NM_003319.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | PolyPhen benign (0.169); catalogued as rs868604877, COSV60244281; called by muse, mutect2, varscan2
- TTPA | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52647854, COSV99478384; called by muse, mutect2, varscan2
- TUBA3D | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs149332264; called by muse, mutect2, varscan2
- UBE2F | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as rs968464715, COSV56027125; called by muse, mutect2, varscan2
- UMODL1 | c.1519+2T>A p.X507_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV61161144; called by muse, mutect2, varscan2
- UNC13C | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52865650; called by muse, mutect2, varscan2
- VNN3 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99258515; called by muse, mutect2, varscan2
- VPS13C | c.9304G>A p.E3102K (on ENST00000644861 / NM_020821.3; = p.E3059K on NM_017684.5) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV51384375; called by muse, mutect2, varscan2
- VPS35L | c.2353A>T p.I785L | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV51988522; called by muse, mutect2, varscan2
- WBP11 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); catalogued as COSV53764166; called by muse, mutect2, varscan2
- WIPF2 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752639716, COSV60275129; called by muse, mutect2, varscan2
- XKR3 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0.031); catalogued as rs1422138117, COSV58886309, COSV58888038; called by muse, mutect2, varscan2
- ZC3HAV1 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 38/73 reads (52%) | catalogued as COSV54299437; called by muse, mutect2, varscan2
- ZFHX4 | c.4508G>A p.G1503E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV50572848, COSV51484077; called by muse, mutect2, varscan2
- ZNF287 | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67688893; called by muse, varscan2
- ZNF608 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs763707632, COSV60440267; called by muse, mutect2, varscan2
- ZNF710 | c.1688T>C p.L563P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV51564854; called by muse, mutect2, varscan2
- EDNRB | c.839dup p.S281Efs*8 (on ENST00000377211 / NM_001201397.1; = p.S191Efs*8 on NM_000115.5) | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SACS | c.8867del p.L2956* | Frame Shift Del (DEL) | VAF 30/61 reads (49%) | called by mutect2, pindel, varscan2
- ABCA4 | c.6618C>T p.L2206= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV64676265; called by muse, mutect2, varscan2
- ABCC3 | c.1998G>A p.G666= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs767255990, COSV53326700; called by muse, mutect2, varscan2
- ADAMTS10 | c.312G>A p.V104= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV54351785, COSV54357613; called by muse, mutect2, varscan2
- ADAMTS3 | c.2076A>G p.E692= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV54398488; called by muse, mutect2, varscan2
- ADGRV1 | c.1683T>A p.P561= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV67992125; called by muse, mutect2, varscan2
- ADGRV1 | c.16533G>A p.K5511= | Silent (SNP) | VAF 73/192 reads (38%) | catalogued as COSV67992128; called by muse, mutect2, varscan2
- ADORA1 | c.621C>T p.I207= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs1558140609, COSV55143677; called by muse, mutect2, varscan2
- AGRN | c.1557C>T p.A519= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs146185843; ClinVar: likely benign; called by muse, varscan2
- AHNAK | c.9615T>C p.P3205= | Silent (SNP) | VAF 86/149 reads (58%) | catalogued as COSV57224771; called by muse, mutect2, varscan2
- AHNAK2 | c.1749C>T p.P583= | Silent (SNP) | VAF 91/238 reads (38%) | catalogued as COSV60924779; called by muse, mutect2, varscan2
- ALDH18A1 | c.282C>T p.R94= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV64663300; called by muse, mutect2, varscan2
- AP4B1 | c.291C>T p.P97= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs1272656306, COSV56726340; called by muse, mutect2, varscan2
- ARHGEF10 | c.357C>T p.I119= (on ENST00000398564; = p.I95= on NM_014629.4) | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs539543107, COSV50657613; called by muse, varscan2
- ASXL3 | c.4536G>A p.Q1512= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs538610692, COSV52474710; called by muse, mutect2, varscan2
- ATP6V0D1 | c.654C>T p.R218= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as rs776138499, COSV52099351; called by muse, mutect2, varscan2
- BICRA | c.3276G>A p.Q1092= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV67604923, COSV67605879; called by muse, mutect2, varscan2
- BRINP3 | c.2124C>T p.D708= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV66535308; called by muse, mutect2, varscan2
- CA3 | c.471G>A p.Q157= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs750340485, COSV53410981; called by muse, mutect2, varscan2
- CACNA1G | c.5520C>T p.F1840= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs770082668, COSV61720840; called by muse, mutect2, varscan2
- CANT1 | c.183C>T p.S61= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV56606302; called by muse, mutect2, varscan2
- CAPSL | c.487C>T p.L163= | Silent (SNP) | VAF 72/174 reads (41%) | catalogued as COSV68439059; called by muse, mutect2, varscan2
- CD5 | c.108G>A p.R36= | Silent (SNP) | VAF 44/68 reads (65%) | catalogued as rs141935047; called by muse, mutect2, varscan2
- CDS1 | c.303C>T p.F101= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs1450264254, COSV55689941; called by muse, mutect2, varscan2
- CILP | c.327C>T p.V109= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV56026783; called by muse, mutect2, varscan2
- CLDN25 | c.621C>T p.S207= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV101493613; called by muse, mutect2, varscan2
- COL11A2 | c.4449A>G p.G1483= (on ENST00000341947 / NM_080680.3; = p.G1376= on NM_080679.2) | Silent (SNP) | VAF 31/46 reads (67%) | catalogued as COSV59500612; called by muse, mutect2, varscan2
- COL14A1 | c.684C>T p.L228= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV52863649; called by muse, mutect2, varscan2
- CTC1 | c.399C>T p.L133= | Silent (SNP) | VAF 61/185 reads (33%) | catalogued as rs899111647, COSV59854627; called by muse, mutect2, varscan2
- CYP39A1 | c.294A>G p.Q98= | Silent (SNP) | VAF 37/42 reads (88%) | catalogued as COSV51498185; called by muse, mutect2, varscan2
- DCAF4L1 | c.963T>C p.H321= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs990238916, COSV60788215; called by muse, mutect2, varscan2
- DDX39B | c.151C>T p.L51= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as COSV58215017; called by muse, mutect2, varscan2
- DNAH7 | c.2013G>A p.R671= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs373012562; called by muse, mutect2, varscan2
- ETF1 | c.363T>C p.N121= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV62127905; called by muse, mutect2, varscan2
- EXOC6 | c.1669C>T p.L557= | Silent (SNP) | VAF 108/296 reads (36%) | catalogued as COSV53330211; called by muse, mutect2, varscan2
- FAM47C | c.1503G>A p.E501= | Silent (SNP) | VAF 39/52 reads (75%) | catalogued as rs782349198, COSV63729189; called by muse, mutect2, varscan2
- FGFR4 | c.1758C>T p.F586= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99450587; called by muse, mutect2, varscan2
- FNTA | c.726C>T p.F242= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs777693422, COSV56491160; called by muse, mutect2, varscan2
- GABRA1 | c.1206C>T p.P402= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as rs541335259, COSV50113670; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GABRE | c.858C>T p.V286= | Silent (SNP) | VAF 72/86 reads (84%) | catalogued as COSV64820760; called by muse, mutect2, varscan2
- GALNT14 | c.1005C>T p.F335= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV61109215; called by muse, mutect2, varscan2
- GCOM1 | c.621G>A p.R207= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV51094831; called by muse, mutect2, varscan2
- GIMAP6 | c.198C>T p.F66= | Silent (SNP) | VAF 112/259 reads (43%) | catalogued as rs199567311, COSV61033514; called by muse, mutect2, varscan2
- GMEB2 | c.804C>T p.V268= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV56608790; called by muse, mutect2, varscan2
- GOT1 | c.774C>T p.S258= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV65147717; called by muse, mutect2, varscan2
- GPR171 | c.132G>A p.T44= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs763446113, COSV56390853; called by muse, mutect2, varscan2
- GPR176 | c.633C>T p.I211= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV54447363; called by muse, mutect2, varscan2
- GTF3C1 | c.2430C>T p.L810= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV62243690; called by muse, mutect2, varscan2
- ICAM2 | c.702G>A p.L234= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs777540468, COSV56742957, COSV56744079; called by mutect2, varscan2
- IFI16 | c.2205C>T p.L735= (on ENST00000295809 / NM_001364867.2; = p.L679= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV55538250; called by muse, mutect2, varscan2
- IGHV3-48 | c.27C>T p.F9= | Silent (SNP) | VAF 61/159 reads (38%) | called by muse, mutect2, varscan2
- IGSF1 | c.3519C>T p.F1173= | Silent (SNP) | VAF 104/135 reads (77%) | catalogued as COSV100812399, COSV63839221; called by muse, mutect2, varscan2
- ITGA4 | c.1419A>G p.L473= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as COSV52002797; called by muse, mutect2, varscan2
- ITGAV | c.1557G>A p.R519= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99654193; called by muse, mutect2, varscan2
- KCNMA1 | c.3063C>T p.D1021= (on ENST00000286628 / NM_001161352.2; = p.D963= on NM_002247.4) | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV54272482; called by muse, mutect2, varscan2
- KNOP1 | c.804A>G p.K268= | Silent (SNP) | VAF 61/136 reads (45%) | catalogued as COSV54929309; called by muse, mutect2, varscan2
- KRI1 | c.1443C>T p.P481= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs773868539, COSV57265475; called by muse, mutect2, varscan2
- KRTAP10-7 | c.501G>A p.G167= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV100170270; called by muse, mutect2, varscan2
- KRTAP4-4 | c.87C>T p.T29= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV66811453; called by muse, mutect2, varscan2
- LCE2A | c.171G>A p.G57= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs61812671, COSV100909212, COSV64227066; called by muse, mutect2, varscan2
- M1AP | c.498C>T p.D166= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as COSV51843063; called by mutect2, varscan2
- MAVS | c.1461G>A p.A487= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs767756615, COSV63926543, COSV63927348; called by muse, mutect2, varscan2
- MGAM | c.1917C>T p.S639= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV72075290; called by muse, mutect2, varscan2
- MROH5 | c.2466C>T p.I822= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV71300776; called by muse, mutect2, varscan2
- MUC17 | c.5184T>C p.R1728= | Silent (SNP) | VAF 113/311 reads (36%) | catalogued as rs1562810179, COSV60298588; called by muse, mutect2, varscan2
- MYH13 | c.5460G>A p.E1820= | Silent (SNP) | VAF 98/240 reads (41%) | catalogued as rs752754610, COSV52835690, COSV52837847; called by muse, varscan2
- MYO18A | c.274C>T p.L92= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100572540; called by muse, mutect2, varscan2
- MYO18A | c.273C>T p.I91= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100572541; called by muse, mutect2, varscan2
- MYO7A | c.4509G>A p.E1503= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV68686362; called by muse, mutect2, varscan2
- NKD1 | c.546G>T p.R182= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV51693467; called by muse, mutect2, varscan2
- NLRP5 | c.570T>C p.I190= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV66764777, COSV66766532; called by muse, varscan2
- NRN1 | c.426C>T p.F142= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs3173505, COSV99784250; called by muse, varscan2
- NRP2 | c.1653G>A p.G551= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV55932918; called by muse, mutect2, varscan2
- NUDT7 | c.606C>T p.I202= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV51744677; called by muse, mutect2, varscan2
- OR10G4 | c.624C>T p.G208= | Silent (SNP) | VAF 52/77 reads (68%) | catalogued as rs144261644, COSV100304655, COSV57978564; called by muse, mutect2, varscan2
- OR2A2 | c.675G>A p.L225= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as rs763035805, COSV68872253; called by muse, mutect2, varscan2
- OR51F2 | c.316C>T p.L106= | Silent (SNP) | VAF 74/127 reads (58%) | catalogued as COSV59063777, COSV59065628; called by muse, mutect2, varscan2
- OR5L1 | c.9G>A p.K3= | Silent (SNP) | VAF 80/138 reads (58%) | catalogued as COSV61734945; called by muse, mutect2, varscan2
- PLCH1 | c.1470C>T p.F490= (on ENST00000340059 / NM_001130960.2; = p.F502= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV58206547; called by muse, mutect2, varscan2
- PODNL1 | c.411C>T p.P137= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV54309453; called by muse, mutect2
- POLR3E | c.21C>T p.D7= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as rs1199416077, COSV55402607; called by muse, mutect2, varscan2
- PPP1R3F | c.2355C>T p.S785= | Silent (SNP) | VAF 31/42 reads (74%) | catalogued as COSV50019571; called by muse, mutect2, varscan2
- PRAMEF14 | c.1347G>A p.R449= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as COSV100577299; called by muse, mutect2, varscan2
- PRSS1 | c.150C>T p.G50= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs765375872, COSV61195812; called by muse, varscan2
- QRICH2 | c.3621C>T p.I1207= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1374481190, COSV53155845; called by mutect2, varscan2
- RANBP10 | c.93G>A p.G31= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV58160143; called by muse, mutect2
- RBM33 | c.1383C>T p.F461= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV56629611, COSV56635860; called by muse, mutect2, varscan2
- RTEL1 | c.2145C>T p.F715= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as rs762607146, COSV58891110; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEPHS2 | c.1242C>T p.A414= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV72100805; called by muse, mutect2, varscan2
- SEZ6L | c.567G>A p.K189= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV50675776; called by muse, varscan2
- SHROOM2 | c.1404G>A p.Q468= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as COSV66609439; called by muse, mutect2, varscan2
- SIX6 | c.318C>T p.P106= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV59803180; called by muse, mutect2, varscan2
- SLC25A20 | c.483G>A p.Q161= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV59804300; called by muse, mutect2, varscan2
- SLC4A10 | c.1671C>T p.L557= (on ENST00000446997 / NM_001354461.2; = p.L527= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV55792625; called by muse, mutect2, varscan2
- SLC8A2 | c.726C>T p.F242= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV52641907; called by mutect2, varscan2
- SLC9A5 | c.792C>T p.L264= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1050220907, COSV55364007; called by muse, mutect2
- SLCO2B1 | c.702C>T p.T234= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV56938243; called by muse, mutect2, varscan2
- SLCO5A1 | c.2253T>A p.I751= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as COSV52665031; called by muse, mutect2, varscan2
- SLX4 | c.2454C>T p.L818= | Silent (SNP) | VAF 101/241 reads (42%) | catalogued as COSV53560753, COSV53567052; called by muse, mutect2, varscan2
- SMARCA4 | c.2877G>A p.E959= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1555779555, COSV60804514; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMPD3 | c.1071G>A p.L357= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV54714567; called by muse, mutect2, varscan2
- SNCAIP | c.2520G>A p.K840= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV54411160; called by muse, mutect2, varscan2
- SPAG17 | c.2550G>A p.L850= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV60466999; called by muse, mutect2, varscan2
- SPEF2 | c.1209C>T p.F403= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV56799331; called by muse, mutect2, varscan2
- SPIRE1 | c.1470C>G p.V490= (on ENST00000409402 / NM_001128626.2; = p.V476= on NM_020148.3) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV59160906; called by muse, mutect2, varscan2
- SSH2 | c.2586C>T p.Y862= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV52178111; called by muse, mutect2, varscan2
- STMN3 | c.147C>T p.A49= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV64247016; called by muse, mutect2, varscan2
- TMEM53 | c.651G>A p.S217= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs1428532190, COSV59191494; called by muse, mutect2, varscan2
- TMEM63C | c.639G>A p.R213= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as rs1442012059, COSV100029628; called by muse, mutect2, varscan2
- TRHDE | c.2013T>C p.T671= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV53830606; called by muse, mutect2, varscan2
- TRIM56 | c.1527G>A p.R509= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV60160630; called by muse, mutect2, varscan2
- TRPC5 | c.1560C>T p.F520= | Silent (SNP) | VAF 62/87 reads (71%) | catalogued as COSV53299185; called by muse, mutect2, varscan2
- TUBA3D | c.789C>T p.P263= | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as rs1272270445, COSV100342779; called by muse, mutect2, varscan2
- VAV1 | c.1422C>T p.I474= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs762320983, COSV100408454, COSV58388860; called by muse, mutect2, varscan2
- VWF | c.4869C>T p.I1623= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV54629844; called by muse, mutect2, varscan2
- WASF3 | c.1092G>A p.Q364= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV58969771; called by muse, mutect2, varscan2
- ZAN | c.1836C>T p.P612= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV61813260; called by muse, mutect2, varscan2
- ZFPL1 | c.552C>T p.P184= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs751567708, COSV99297967; called by muse, mutect2, varscan2
- ZNF229 | c.469C>T p.L157= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV52163955; called by muse, mutect2, varscan2
- ZNF615 | c.492C>T p.S164= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV65034557; called by muse, mutect2, varscan2
- CALCR | c.52-3333T>C | Intron (SNP) | VAF 57/124 reads (46%) | catalogued as COSV100810749; called by muse, mutect2, varscan2
- POM121C | chr7:75416024 T>A | 3'Flank (SNP) | VAF 28/58 reads (48%) | called by mutect2, varscan2
- RNU6-104P | chr8:43304752 C>T | 3'Flank (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- SNORD115-2 | n.34G>A | RNA (SNP) | VAF 70/171 reads (41%) | called by muse, varscan2
- SNORD115-35 | n.55C>T | RNA (SNP) | VAF 83/220 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.10360+2441G>A | Intron (SNP) | VAF 22/53 reads (42%) | catalogued as rs992228158, COSV100623429; called by muse, mutect2, varscan2
- WDPCP | c.500-321G>A | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as rs777454937, COSV99706336; called by mutect2, varscan2
